Gene-level copy-number profile of specimen HCM-BROD-0007-C49-85B from HCMI case HCM-BROD-0007-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed type rhabdomyosarcoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 12.0 years (4,386 days).
Specimen HCM-BROD-0007-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0cb51f57-256c-4d21-aa48-f162ae48e358.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0007-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/beaebaea-b70f-4e34-b5c0-0e6eb030011d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 510; copy number 1: 4,052; copy number 2: 54,054; copy number 3: 232; copy number 4: 43; copy number 144: 21.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–127,636,867, 1 gene: AC104370.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,801,747–16,666,331, 21 genes, copy number 144: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA.

Autosomal genes at a single copy (total copy number 1): 1,710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
